MMRF case MMRF_1587 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/22a9556f-238b-46c1-a6d9-c57ed8cdc2b2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Dead; Days to death: 629 days (1.7 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 74.6 years (27,232 days); ISS stage: III; Days to last known disease status: 629 days (1.7 years); Days to last follow up: 629 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 167 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 190 days; Days to treatment end: 234 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 234 days; Days to treatment end: 298 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 238 days; Days to treatment end: 298 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 309 days; Days to treatment end: 672 days (1.8 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 309 days; Days to treatment end: 550 days (1.5 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 629.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 4.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 116 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 142 mg/dL; Immunoglobulin G 69.1 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 9 µg/mL; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 5.15 mmol/L; Leukocytes 13.6 ×10⁹/L; Absolute Neutrophil 5.9 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.4 mmol/L; Albumin 33 g/L; Total Protein 11.2 g/dL; Glucose 6.44 mmol/L; C-Reactive Protein 0.04 mg/dL.
- Day 85 (ECOG 0): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 13.2 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 4.5 µg/mL; Hemoglobin 7.75 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 1.33 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 13.3 mmol/L.
- Day 186 (ECOG 0): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 5.2 µg/mL; Hemoglobin 7.75 mmol/L; Leukocytes 11.2 ×10⁹/L; Absolute Neutrophil 6.5 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 7.5 g/dL; Glucose 6.16 mmol/L.
- Day 270 (ECOG 0): M Protein 3.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 137 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Immunoglobulin G 41.4 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 19.6 µg/mL; Hemoglobin 5.46 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 44 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.03 mmol/L; Albumin 30 g/L; Total Protein 8.2 g/dL; Glucose 12.9 mmol/L.
- Day 368 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.114 mg/dL; Immunoglobulin G 6.82 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 6.4 µg/mL; Hemoglobin 7.44 mmol/L; Leukocytes 6.12 ×10⁹/L; Absolute Neutrophil 4.59 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 212 µmol/L; Blood Urea Nitrogen 12.1 mmol/L; Calcium 2.1 mmol/L; Albumin 36 g/L; Total Protein 6.8 g/dL; Glucose 6.66 mmol/L.
- Day 449 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.542 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.229 mg/dL; Immunoglobulin G 6.71 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 10.9 µg/mL; Hemoglobin 6.14 mmol/L; Leukocytes 3.73 ×10⁹/L; Absolute Neutrophil 1.77 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 203 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.13 mmol/L; Albumin 36 g/L; Total Protein 5.6 g/dL; Glucose 8.53 mmol/L.
- Day 564 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Immunoglobulin G 9.13 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 10.8 µg/mL; Hemoglobin 5.89 mmol/L; Leukocytes 3.94 ×10⁹/L; Absolute Neutrophil 2.33 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 212 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 5.94 mmol/L.
- Day 620 (ECOG 1): M Protein 1.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 149 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Immunoglobulin G 20.1 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 26.6 µg/mL; Hemoglobin 5.7 mmol/L; Leukocytes 7.66 ×10⁹/L; Absolute Neutrophil 3.93 ×10⁹/L; Platelets 68 ×10⁹/L; Creatinine 239 µmol/L; Blood Urea Nitrogen 14.3 mmol/L; Calcium 2.33 mmol/L; Albumin 35 g/L; Total Protein 7.4 g/dL; Glucose 7.87 mmol/L.

Other clinical attributes
- Day 1: Weight: 88 kg; Height: 181 cm.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample MMRF_1587_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1587_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
- Sample MMRF_1587_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 564 days (1.5 years).
